Somatic mutation profile of tumor specimen TCGA-YC-A89H-01A (aliquot TCGA-YC-A89H-01A-11D-A364-08) from TCGA case TCGA-YC-A89H, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 78.7 years (28,741 days).
Specimen TCGA-YC-A89H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296b9449-0068-469b-aed0-5056a21907dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YC-A89H-10A (Blood Derived Normal), aliquot TCGA-YC-A89H-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae03d51-b2fc-44cb-a9b5-8f670f0d3ab4

The open-access MAF lists 1,937 somatic variants for this specimen: 1,283 protein-altering or splice-affecting, 602 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,098, Silent 602, Nonsense Mutation 116, Splice Site 24, Intron 23, Frame Shift Del 15, Splice Region 11, 5'UTR 9, In Frame Del 7, 3'UTR 6, Translation Start Site 6, Frame Shift Ins 5.

Variants (750 of 1,937; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 61/138 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2
- CSNK2A1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs869312845, COSV53935145; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2, varscan2
- ERCC2 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101228885, COSV67268042; called by muse, mutect2, varscan2
- KRT86 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs121909129, CM970853, COSV53292673; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV99771454; called by muse, mutect2
- AASDHPPT | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750664593, COSV53789034; called by muse, mutect2, varscan2
- ABCA12 | c.6089A>G p.Y2030C (on ENST00000272895 / NM_173076.3; = p.Y1712C on NM_015657.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764148814, COSV55959125; called by muse, mutect2, varscan2
- ABCA12 | c.5053G>A p.G1685R (on ENST00000272895 / NM_173076.3; = p.G1367R on NM_015657.3) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.427); catalogued as rs1406689344, COSV55959142; called by muse, mutect2, varscan2
- ABCC4 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1396775428, COSV65312588; called by muse, mutect2, varscan2
- ABCG2 | c.648A>C p.L216F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946016; called by muse, mutect2, varscan2
- ABHD12 | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | catalogued as rs762526719, COSV59285724; called by muse, varscan2
- AC011462.1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs200961973; called by muse, mutect2, varscan2
- ACLY | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV100044436, COSV59861997, COSV59862291; called by muse, mutect2, varscan2
- ACOT1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs746571011, COSV58570601; called by muse, mutect2, varscan2
- ACOX3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV62711984; called by muse, mutect2, varscan2
- ACSBG2 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs1245901336, COSV53124605; called by muse, mutect2, varscan2
- ACTG1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV59510446; called by muse, mutect2, varscan2
- ACTR10 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772399098, COSV54298488; called by muse, mutect2, varscan2
- ACTRT2 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65759341; called by muse, mutect2, varscan2
- ACTRT2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65759348; called by muse, mutect2, varscan2
- ADAM17 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as rs986450748, COSV60398810; called by muse, mutect2, varscan2
- ADAM17 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV60398818, COSV60402569; called by muse, mutect2, varscan2
- ADAM9 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65959991; called by muse, mutect2, varscan2
- ADAMTS19 | c.1782C>A p.C594* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99178851; called by muse, mutect2, varscan2
- ADAT1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57186550; called by muse, varscan2
- ADCK1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV53080769; called by muse, mutect2, varscan2
- ADCY2 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1481992591, COSV57872133; called by muse, varscan2
- ADCY4 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60254229; called by muse, mutect2, varscan2
- ADD3 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53322314; called by muse, mutect2, varscan2
- ADGRD1 | c.2404A>C p.I802L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV55445191; called by muse, mutect2, varscan2
- ADGRG2 | c.1493A>G p.N498S (on ENST00000379869 / NM_001079858.3; = p.N495S on NM_005756.4) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV61339095; called by muse, mutect2, varscan2
- ADGRG7 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56295442, COSV56296535; called by muse, mutect2, varscan2
- ADGRV1 | c.9244G>A p.E3082K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV67985014; called by muse, mutect2, varscan2
- ADGRV1 | c.12803G>A p.R4268Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1326096741, COSV67985018; called by muse, mutect2, varscan2
- ADRB2 | c.1116A>C p.K372N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV60005496; called by muse, mutect2, varscan2
- ADSS1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.142); catalogued as COSV58273409; called by muse, mutect2, varscan2
- AFDN | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV60044391; called by muse, mutect2, varscan2
- AFF1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.438); catalogued as COSV57119747; called by muse, mutect2, varscan2
- AFTPH | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867709578, COSV53217051; called by muse, mutect2
- AGO3 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV55793375; called by muse, mutect2, varscan2
- AGTPBP1 | c.3248C>A p.S1083Y (on ENST00000357081 / NM_001330701.2; = p.S1043Y on NM_015239.2) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV61271556; called by muse, mutect2, varscan2
- AGXT2 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as rs1413471163, COSV99183756; called by muse, mutect2, varscan2
- AHCTF1 | c.2703G>A p.M901I (on ENST00000366508; = p.M875I on NM_015446.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58249815; called by muse, mutect2, varscan2
- AHNAK2 | c.16135G>T p.D5379Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60915147; called by muse, mutect2, varscan2
- AHNAK2 | c.10828G>T p.A3610S | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60915162; called by muse, mutect2, varscan2
- AHNAK2 | c.10827G>C p.Q3609H | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV60915173; called by muse, mutect2, varscan2
- AK8 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53754248; called by muse, mutect2, varscan2
- AKAP13 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs767360299, COSV63456891; called by muse, mutect2, varscan2
- AKAP13 | c.4992+2T>C p.X1664_splice (on ENST00000394518 / NM_007200.5; = p.X1668_splice on NM_006738.6) | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV63456904; called by muse, mutect2, varscan2
- AKAP13 | c.7915G>A p.E2639K (on ENST00000394518 / NM_007200.5; = p.E2643K on NM_006738.6) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV100773818; called by muse, mutect2, varscan2
- AKAP7 | c.883G>A p.E295K (on ENST00000431975 / NM_016377.4; = p.E28K on NM_004842.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1468409713, COSV53834953; called by muse, mutect2, varscan2
- AKAP9 | c.5375C>A p.S1792Y (on ENST00000359028; = p.S1760Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62346044; called by muse, mutect2, varscan2
- AKAP9 | c.6724G>A p.E2242K (on ENST00000359028; = p.E2218K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1487087847, COSV62346060; called by muse, mutect2, varscan2
- AKAP9 | c.10165G>A p.E3389K (on ENST00000359028; = p.E3365K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1167367385, COSV100662437, COSV62346073, COSV62350356; called by muse, mutect2, varscan2
- AKR1C2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); catalogued as COSV101060471; called by muse, mutect2, varscan2
- AKT1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1319030326, COSV62573353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.3513C>T p.I1171= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV66566454, COSV66567946; called by muse, mutect2, varscan2
- ALK | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1365924896, COSV66563948; called by muse, mutect2, varscan2
- ALKBH1 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.061); catalogued as COSV53659691; called by muse, mutect2, varscan2
- ALPP | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371726976, COSV101235044; called by muse, mutect2, varscan2
- ALS2 | c.4129G>A p.D1377N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV51887000; called by muse, mutect2
- AMPD3 | c.1342G>A p.E448K (on ENST00000396553 / NM_001025389.2; = p.E457K on NM_000480.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV67330903; called by muse, mutect2, varscan2
- ANAPC1 | c.2802G>A p.M934I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61975974; called by muse, mutect2, varscan2
- ANAPC15 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV56191845; called by muse, mutect2, varscan2
- ANGPTL6 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99463694; called by muse, mutect2
- ANKFY1 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs370516432; called by muse, mutect2, varscan2
- ANKRD12 | c.4718C>T p.S1573L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV50819054; called by muse, mutect2, varscan2
- ANKRD40 | c.771T>A p.N257K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV53333503; called by muse, mutect2, varscan2
- ANKRD40 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1374107193, COSV53333516; called by muse, mutect2, varscan2
- ANKRD50 | c.1153T>A p.F385I | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV72385545; called by muse, mutect2, varscan2
- ANKRD6 | c.2016dup p.E673* (on ENST00000339746 / NM_001242809.2; = p.E668* on NM_014942.4) | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs751514998; called by mutect2, varscan2
- ANO1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367716754; called by muse, mutect2
- ANO4 | c.1328A>G p.E443G (on ENST00000392977 / NM_001286615.2; = p.E408G on NM_178826.4) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV54595532; called by muse, mutect2, varscan2
- ANO4 | c.2584C>T p.R862C (on ENST00000392977 / NM_001286615.2; = p.R827C on NM_178826.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774274653, COSV54595545; called by muse, mutect2, varscan2
- ANXA9 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV64484790; called by muse, mutect2, varscan2
- AOAH | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51741267; called by muse, mutect2, varscan2
- AP002748.5 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59148611; called by muse, mutect2, varscan2
- AP1G2 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58112467; called by muse, mutect2, varscan2
- AP3B1 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54883724; called by muse, mutect2, varscan2
- APLP2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV53840720; called by muse, mutect2, varscan2
- APOL2 | c.802A>C p.M268L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV50772096; called by muse, mutect2, varscan2
- ARFGEF1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV51608555; called by muse, mutect2, varscan2
- ARGLU1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV62271552, COSV62271999; called by muse, varscan2
- ARHGEF12 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV63104602; called by muse, mutect2, varscan2
- ARHGEF12 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV63104605; called by muse, mutect2, varscan2
- ARHGEF15 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100730050; called by muse, mutect2, varscan2
- ARHGEF37 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV61368711; called by muse, mutect2, varscan2
- ARHGEF39 | c.990C>T p.I330= | Splice Region (SNP) | VAF 28/49 reads (57%) | catalogued as COSV58397150; called by muse, mutect2, varscan2
- ARHGEF7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV57741548; called by muse, mutect2
- ARID1A | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV61374388, COSV61381125; called by muse, mutect2, varscan2
- ARID1A | c.2879-2A>G p.X960_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61377336, COSV61377498, COSV99055340; called by muse, mutect2, varscan2
- ARID5B | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs757763429, COSV54414394, COSV54414704, COSV54420304; called by muse, mutect2, varscan2
- ARMC8 | c.1624C>T p.R542C (on ENST00000469044 / NM_001363941.2; = p.R528C on NM_015396.6) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58618719; called by muse, mutect2, varscan2
- ARMH4 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs148257737; called by muse, mutect2, varscan2
- ARMH4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV50764368; called by muse, mutect2, varscan2
- ARNT2 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57585169; called by muse, mutect2, varscan2
- ARPP21 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51797632; called by muse, mutect2, varscan2
- ARSK | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV66169654; called by muse, mutect2, varscan2
- ART3 | c.886A>T p.N296Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV61914035; called by muse, mutect2, varscan2
- ASH1L | c.7534G>A p.D2512N (on ENST00000368346 / NM_001366177.2; = p.D2507N on NM_018489.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100853482, COSV64207940; called by muse, mutect2, varscan2
- ASH1L | c.2877G>A p.M959I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs775491536, COSV64207943; called by muse, mutect2, varscan2
- ASIC5 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs746546867, COSV73332717; called by muse, mutect2, varscan2
- ASPHD1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.834); catalogued as COSV58098207; called by muse, mutect2, varscan2
- ASRGL1 | c.341A>T p.H114L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57124607; called by muse, mutect2, varscan2
- ASXL3 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99324993; called by muse, mutect2, varscan2
- ASXL3 | c.6418C>T p.Q2140* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99324996; called by muse, mutect2, varscan2
- ASZ1 | c.1238G>C p.S413T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV52912803; called by muse, mutect2, varscan2
- ATAD5 | c.5107C>T p.Q1703* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100429969; called by muse, mutect2, varscan2
- ATG2A | c.4004G>T p.G1335V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV65966800; called by muse, mutect2, varscan2
- ATG2A | c.4003G>T p.G1335C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV65966805; called by muse, mutect2, varscan2
- ATG4C | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs760611137, COSV100508160, COSV58605534; called by muse, mutect2, varscan2
- ATP6AP1 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.127); catalogued as rs781946895, COSV62340993, COSV62341047; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs199698721, COSV57749267; called by muse, mutect2, varscan2
- ATP6V0D2 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1373273433, COSV53414934; called by muse, mutect2, varscan2
- ATP7A | c.4043C>G p.S1348* | Nonsense Mutation (SNP) | VAF 8/117 reads (7%) | catalogued as COSV100430851; called by muse, mutect2
- ATP8B3 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99402343; called by muse, mutect2
- ATRN | c.2870A>G p.Q957R | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs753407058, COSV53527696; called by muse, mutect2
- ATRX | c.1720A>G p.I574V | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV64876427; called by muse, mutect2
- AWAT2 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1453908417, COSV99339666; called by muse, mutect2, varscan2
- B3GALT5 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.618); catalogued as COSV58198771; called by muse, mutect2, varscan2
- B4GAT1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV60820087; called by muse, mutect2, varscan2
- BCAR3 | c.1975-1G>A p.X659_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV53074909; called by muse, mutect2
- BCL9L | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV52684271; called by muse, mutect2, varscan2
- BEST3 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56994652; called by mutect2, varscan2
- BICC1 | c.1590T>G p.I530M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); catalogued as COSV54063662; called by muse, mutect2, varscan2
- BICD2 | c.2080C>A p.R694S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs797045412; called by muse, mutect2
- BICD2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs142503252; called by muse, mutect2, varscan2
- BIRC6 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70199136; called by muse, mutect2, varscan2
- BLNK | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV56410038, COSV56410858; called by muse, mutect2, varscan2
- BLZF1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV61393075; called by muse, mutect2, varscan2
- BRAP | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58156668; called by muse, mutect2, varscan2
- BRCA2 | c.9257G>A p.G3086E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574271678, COSV66453625; called by muse, mutect2, varscan2
- BRD1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs775142763, COSV53457347; called by muse, mutect2, varscan2
- BRD2 | c.333G>T p.P111= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV66373292; called by muse, varscan2
- BRSK1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs757271976, COSV58666512; called by muse, mutect2, varscan2
- BRWD1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as COSV58122763; called by muse, mutect2, varscan2
- BSG | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1186315385, COSV61076939; called by muse, mutect2, varscan2
- C10orf90 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs764588711, COSV52955071; called by muse, mutect2, varscan2
- C11orf58 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV57178549; called by muse, mutect2, varscan2
- C11orf58 | c.148-1G>A p.X50_splice | Splice Site (SNP) | VAF 20/73 reads (27%) | catalogued as COSV57178553; called by muse, mutect2, varscan2
- C16orf71 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99556329; called by muse, mutect2, varscan2
- C1orf116 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV63944053; called by muse, mutect2, varscan2
- C1orf116 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63943979, COSV63944056; called by muse, mutect2, varscan2
- C2CD3 | c.5077C>T p.Q1693* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100486733; called by muse, mutect2, varscan2
- C4BPB | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54691434; called by muse, mutect2, varscan2
- C6orf120 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV59321055; called by muse, mutect2, varscan2
- C6orf58 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs1347316496, COSV100314883; called by muse, mutect2, varscan2
- C6orf62 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100965867; called by muse, mutect2, varscan2
- CA7 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1293380175, COSV58156431; called by muse, mutect2, varscan2
- CABP7 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53363097; called by muse, mutect2, varscan2
- CABS1 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as COSV56733566; called by muse, mutect2, varscan2
- CADPS | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs748581967, COSV99339173; called by muse, mutect2, varscan2
- CADPS | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51879571; called by muse, mutect2, varscan2
- CALCOCO2 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV51951924; called by muse, mutect2, varscan2
- CAMSAP2 | c.1924G>A p.D642N (on ENST00000236925 / NM_001297707.2; = p.D631N on NM_203459.3) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52670293; called by muse, mutect2, varscan2
- CAMSAP3 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV50334371; called by muse, mutect2, varscan2
- CAMTA2 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61834847; called by muse, mutect2, varscan2
- CAP1 | c.558T>A p.Y186* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100472354; called by muse, mutect2
- CAPN10 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.124); catalogued as COSV54374779, COSV54376566; called by muse, mutect2, varscan2
- CAPN3 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58820789; called by muse, mutect2, varscan2
- CAPN6 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV60694962; called by muse, mutect2, varscan2
- CARD14 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs369150206; called by muse, mutect2, varscan2
- CARD6 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as rs906424010, COSV54566160; called by muse, varscan2
- CARD6 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54566176; called by muse, varscan2
- CARMIL3 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV57726331; called by muse, mutect2, varscan2
- CARS1 | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs766036181, COSV53454234; called by muse, mutect2, varscan2
- CASP1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV62056518; called by muse, mutect2, varscan2
- CASP2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.174); catalogued as rs758747020, COSV60082215; called by muse, mutect2, varscan2
- CASP8AP2 | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1289256611, COSV99386805, COSV99387071; called by muse, mutect2, varscan2
- CASQ2 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54770415; called by muse, mutect2, varscan2
- CAT | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53811184; called by muse, mutect2, varscan2
- CAVIN2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1218345828, COSV58424152; called by muse, mutect2, varscan2
- CBFA2T2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1159215415, COSV60073145; called by muse, mutect2
- CBFA2T2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60074062; called by muse, mutect2
- CBX1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV56681862; called by muse, mutect2, varscan2
- CBX3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs1163566185, COSV61761390; called by muse, mutect2, varscan2
- CCAR1 | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV56266753, COSV99771055; called by muse, mutect2, varscan2
- CCDC138 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs896059293, COSV54567061; called by muse, mutect2, varscan2
- CCDC30 | c.730G>A p.E244K (on ENST00000340612; = p.E201K on NM_001080850.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs376480393, COSV59604377; called by muse, mutect2, varscan2
- CCDC33 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.04); catalogued as rs1278584193, COSV58351742; called by muse, mutect2, varscan2
- CCDC33 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1296319075, COSV100351417; called by muse, mutect2, varscan2
- CCDC62 | c.779G>C p.R260T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775259284, COSV53433444; called by muse, mutect2, varscan2
- CCDC80 | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as COSV52816719, COSV99244399; called by muse, mutect2, varscan2
- CCDC81 | c.590G>A p.R197K (on ENST00000445632 / NM_001156474.2; = p.R107K on NM_021827.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.843); catalogued as COSV53578220; called by muse, mutect2, varscan2
- CCDC90B | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as rs538799582, COSV99475315; called by muse, mutect2, varscan2
- CCDC96 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs369900664; called by muse, mutect2, varscan2
- CCDC9B | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV66875402; called by muse, mutect2, varscan2
- CCN1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs768362037, COSV71704266; called by muse, mutect2, varscan2
- CCN2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.159); catalogued as COSV63466538; called by muse, mutect2, varscan2
- CCNE2 | c.923A>C p.E308A | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV57376009; called by muse, mutect2, varscan2
- CCNG2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV60353639; called by muse, mutect2, varscan2
- CCT7 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as rs756728346, COSV57822065; called by muse, mutect2, varscan2
- CCT8L2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV63462408; called by muse, mutect2, varscan2
- CD101 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144225932; called by muse, mutect2, varscan2
- CD40LG | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV65698478, COSV65698493; called by muse, mutect2
- CDA | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV66751646; called by muse, mutect2, varscan2
- CDC42BPG | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs147422193, COSV100712180; called by muse, varscan2
- CDK12 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.945); catalogued as rs759485356, COSV70999458, COSV71000630; called by muse, varscan2
- CDK7 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV56513406; called by muse, mutect2, varscan2
- CDK9 | c.435C>T p.I145= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs1412326548, COSV64723739; called by muse, mutect2, varscan2
- CEACAM5 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55752181; called by muse, mutect2, varscan2
- CELSR3 | c.9599C>G p.S3200C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV50858824; called by muse, mutect2, varscan2
- CELSR3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770585899, COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CEMIP2 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs138676811, COSV65487216; called by muse, mutect2, varscan2
- CENPF | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV65274924; called by muse, mutect2, varscan2
- CEP170 | c.4378G>C p.E1460Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100317105; called by muse, mutect2, varscan2
- CEP170 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100317108; called by muse, mutect2, varscan2
- CEP290 | c.6110C>T p.S2037L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as rs1173252668, COSV100468763; called by muse, mutect2
- CEP95 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV73609079, COSV73609155; called by muse, mutect2, varscan2
- CERCAM | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1469721595, COSV100864154, COSV65710553; called by muse, mutect2, varscan2
- CFAP44 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55611295; called by muse, mutect2, varscan2
- CFAP54 | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV61572150; called by muse, mutect2, varscan2
- CFD | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as COSV99708737; called by muse, mutect2, varscan2
- CH25H | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV64092317; called by muse, mutect2, varscan2
- CHD2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV59120251; called by muse, mutect2, varscan2
- CHD2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV59120270; called by muse, mutect2, varscan2
- CHD5 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52414265; called by muse, mutect2, varscan2
- CHD9 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.331); catalogued as COSV54610330; called by muse, mutect2, varscan2
- CHEK2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as rs779269031, CM136260, COSV60420129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHI3L2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as rs1056743191, COSV100869289; called by muse, mutect2, varscan2
- CHORDC1 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV57706011; called by muse, mutect2, varscan2
- CHRNA10 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs768300880, COSV51703014; called by muse, mutect2, varscan2
- CHRNA6 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.585); catalogued as rs1294417545, COSV52379523; called by muse, mutect2, varscan2
- CHTF8 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706995; called by muse, mutect2, varscan2
- CLASRP | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs903835656, COSV55516216; called by muse, mutect2, varscan2
- CLCA4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.792); catalogued as COSV55368170; called by muse, mutect2, varscan2
- CLEC14A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV60562542; called by muse, mutect2, varscan2
- CLEC3B | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56109775; called by muse, mutect2, varscan2
- CLK4 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1386049975, COSV60317527, COSV60318737; called by muse, mutect2, varscan2
- CLOCK | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs780854851, COSV59401826; called by muse, mutect2, varscan2
- CMYA5 | c.3916G>A p.D1306N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs761701466, COSV71405843; called by muse, mutect2
- CNNM1 | c.2046G>T p.E682D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100763868, COSV63203695; called by muse, mutect2, varscan2
- CNNM2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV63995907; called by muse, mutect2, varscan2
- CNNM2 | c.2511G>C p.L837F | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV63998590; called by muse, mutect2, varscan2
- CNNM4 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65660790; called by muse, mutect2, varscan2
- CNOT1 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55316550; called by muse, mutect2, varscan2
- CNTLN | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs1479784759, COSV52078280; called by muse, mutect2, varscan2
- CNTNAP2 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62179727, COSV62201657; called by muse, mutect2, varscan2
- COBL | c.3060C>G p.D1020E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV54345516; called by muse, mutect2, varscan2
- COL14A1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52851310, COSV52854219; called by muse, mutect2, varscan2
- COL25A1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211430; called by muse, mutect2
- COL3A1 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as CM1512470; called by muse, mutect2
- COL4A3 | c.2852T>C p.I951T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1429805281, COSV100516742; called by muse, mutect2
- COL4A4 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.388); catalogued as COSV61632118; called by muse, mutect2, varscan2
- COL8A2 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as COSV100291191; called by muse, mutect2
- COPB2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60812531; called by muse, mutect2, varscan2
- CORO6 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61470836; called by muse, mutect2, varscan2
- CPLANE1 | c.7613C>T p.S2538L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57059755; called by muse, mutect2, varscan2
- CPM | c.1321T>C p.F441L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1050912685, COSV58032569; called by muse, mutect2, varscan2
- CPNE9 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56068425; called by muse, varscan2
- CPSF4 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 49/193 reads (25%) | catalogued as COSV99461744; called by muse, mutect2, varscan2
- CPT1C | c.1403del p.V468Gfs*62 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV54919162; called by mutect2, pindel, varscan2
- CPXCR1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV104370548, COSV52162251; called by muse, mutect2, varscan2
- CPZ | c.1210C>T p.P404S (on ENST00000360986 / NM_001014447.3; = p.P393S on NM_003652.3) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV59923017; called by muse, mutect2, varscan2
- CRIM1 | c.1175-1G>A p.X392_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99753428; called by muse, mutect2
- CRY2 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs769583067, COSV69888541; called by muse, varscan2
- CRYBG3 | c.6118G>A p.E2040K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51711894; called by muse, mutect2, varscan2
- CSMD2 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs774023508, COSV53879951, COSV99592538; called by muse, mutect2, varscan2
- CSMD3 | c.9941C>T p.S3314L (on ENST00000297405 / NM_001363185.1; = p.S3145L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.519); catalogued as COSV52178293; called by muse, mutect2
- CSNK2A1 | c.252_255del p.I84Mfs*4 | Frame Shift Del (DEL) | VAF 69/178 reads (39%) | catalogued as COSV53935136; called by mutect2, pindel, varscan2
- CTDP1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs774687256, COSV50003192; called by muse, mutect2, varscan2
- CUL7 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54816927; called by muse, mutect2, varscan2
- CYP2F1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58527421; called by muse, mutect2, varscan2
- CYP2W1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs746365436, COSV58270069; called by muse, mutect2, varscan2
- CYP4A22 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99594920; called by muse, mutect2, varscan2
- CYP4F3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV55409781, COSV55413113; called by muse, mutect2, varscan2
- CYP4F3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs1050239580, COSV55409798; called by muse, mutect2, varscan2
- D2HGDH | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58320796; called by muse, varscan2
- DCAF12 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV63512492; called by muse, mutect2, varscan2
- DCAF5 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV58460297, COSV58462703; called by muse, mutect2, varscan2
- DCN | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771882946, COSV50007101; called by muse, mutect2, varscan2
- DCP1A | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as rs1553692976, COSV53687492; called by muse, mutect2, varscan2
- DDB2 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57038626; called by muse, mutect2, varscan2
- DDHD2 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV68157844; called by muse, mutect2, varscan2
- DDX11 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs549481531, COSV52504096; called by muse, mutect2, varscan2
- DDX17 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV53247687; called by muse, mutect2, varscan2
- DDX20 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV63831068; called by muse, mutect2, varscan2
- DDX41 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV57903449; called by muse, mutect2, varscan2
- DDX42 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866497677, COSV63789241; called by muse, mutect2, varscan2
- DDX42 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63790102; called by muse, mutect2, varscan2
- DDX5 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56749063; called by muse, mutect2, varscan2
- DDX54 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58373508; called by muse, mutect2, varscan2
- DDX54 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV58373517; called by muse, mutect2, varscan2
- DEDD2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs372748160; called by muse, mutect2, varscan2
- DEFB129 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.505); catalogued as COSV55731390; called by muse, mutect2, varscan2
- DENND2C | c.1450G>A p.E484K (on ENST00000393274 / NM_001256404.2; = p.E427K on NM_198459.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1385139597, COSV67921711; called by muse, mutect2, varscan2
- DENND4A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1159809331, COSV101475344; called by muse, mutect2, varscan2
- DENND6A | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1333248643, COSV60768637, COSV60768683; called by muse, mutect2, varscan2
- DFFA | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV65477461; called by muse, mutect2, varscan2
- DGLUCY | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1056423148, COSV56366322; called by muse, mutect2, varscan2
- DHX32 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52940146; called by muse, mutect2, varscan2
- DHX32 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52940153; called by muse, mutect2, varscan2
- DHX32 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52940164; called by muse, mutect2, varscan2
- DHX57 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.42); catalogued as COSV54885292; called by muse, mutect2, varscan2
- DISP2 | c.2631G>A p.M877I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV51121695; called by muse, mutect2, varscan2
- DIXDC1 | c.791C>T p.S264F (on ENST00000440460 / NM_001037954.4; = p.S53F on NM_033425.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.237); catalogued as COSV59461873; called by muse, mutect2, varscan2
- DLC1 | c.1221T>G p.N407K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV52303653; called by muse, mutect2, varscan2
- DLG1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58382711; called by muse, mutect2, varscan2
- DLG2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as COSV54643653; called by muse, mutect2, varscan2
- DMBX1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100760779; called by muse, mutect2
- DMRT2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV52401856; called by muse, mutect2, varscan2
- DMTF1 | c.393C>G p.S131R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV58685236; called by muse, mutect2, varscan2
- DMXL2 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51846339; called by muse, mutect2, varscan2
- DMXL2 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99196389; called by muse, mutect2, varscan2
- DNAH7 | c.11722G>A p.E3908K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV56764573; called by muse, mutect2, varscan2
- DNAH8 | c.12544C>T p.H4182Y | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59444764; called by muse, mutect2, varscan2
- DNAJA1 | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100438640, COSV58310363; called by muse, mutect2, varscan2
- DNAJC17 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs755263192, COSV55024969; called by muse, mutect2, varscan2
- DNAJC2 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99971795; called by muse, mutect2
- DNAJC3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1234873959, COSV65131467; called by muse, mutect2, varscan2
- DNMT3B | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV52417945; called by muse, mutect2, varscan2
- DOCK2 | c.379T>C p.W127R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV56958219; called by muse, mutect2, varscan2
- DOCK3 | c.5893C>T p.Q1965* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99812147; called by muse, mutect2, varscan2
- DOCK6 | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99370980; called by muse, mutect2, varscan2
- DOK1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51207488, COSV51216457, COSV99284105; called by muse, mutect2, varscan2
- DPYD | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs200687447, CM145312, COSV64591456; called by muse, mutect2, varscan2
- DQX1 | c.429C>T p.L143= | Splice Region (SNP) | VAF 28/80 reads (35%) | catalogued as rs1304195646, COSV57817215; called by muse, mutect2, varscan2
- DRD1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as COSV67104562; called by muse, mutect2, varscan2
- DRG2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as rs1182390928, COSV52756555; called by muse, mutect2, varscan2
- DSC1 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs925724782, COSV57145613; called by muse, mutect2, varscan2
- DTX4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs376061897; called by muse, mutect2
- DUSP1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs1372411767, COSV53319743, COSV53319977; called by muse, mutect2, varscan2
- DYNC1H1 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV64136905; called by muse, mutect2, varscan2
- DYNC2I2 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); catalogued as rs776327242, COSV63987093; called by muse, mutect2, varscan2
- DZIP3 | c.3316C>T p.H1106Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV64312068; called by muse, mutect2, varscan2
- DZIP3 | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV64311461; called by muse, mutect2, varscan2
- E2F8 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV51463398; called by muse, mutect2, varscan2
- EBNA1BP2 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99355965; called by muse, varscan2
- ECEL1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV58812243; called by muse, mutect2, varscan2
- ECPAS | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52196982; called by muse, mutect2, varscan2
- EDEM1 | c.1010G>A p.W337* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99849225; called by muse, mutect2, varscan2
- EDEM1 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99849226; called by muse, mutect2, varscan2
- EDEM3 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1166557608, COSV100545316; called by muse, mutect2, varscan2
- EDRF1 | c.1594G>A p.D532N (on ENST00000356792 / NM_001202438.2; = p.D498N on NM_015608.2) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61763874; called by muse, mutect2, varscan2
- EEA1 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV59285736; called by muse, mutect2, varscan2
- EEF1A1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58548609, COSV58550358; called by muse, mutect2, varscan2
- EEF2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58579461; called by muse, mutect2, varscan2
- EEF2K | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53781781; called by muse, mutect2, varscan2
- EFCAB6 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53063109; called by muse, mutect2, varscan2
- EFL1 | c.2570A>C p.K857T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1567041918, COSV51605438; called by muse, mutect2, varscan2
- EHMT2 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs755793502, COSV57667204, COSV57669409; called by muse, mutect2, varscan2
- EIF2AK2 | c.1596A>G p.I532M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51796291; called by muse, mutect2, varscan2
- EIF4A2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV60623812, COSV60624846; called by muse, mutect2, varscan2
- EIF4A2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV60624854; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57515762; called by muse, mutect2, varscan2
- ELAPOR2 | c.1720C>T p.Q574* (on ENST00000450689 / NM_001142749.3; = p.Q407* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs1437448522, COSV51884170; called by muse, mutect2, varscan2
- ELAPOR2 | c.949G>A p.E317K (on ENST00000450689 / NM_001142749.3; = p.E150K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.185); catalogued as COSV51884745; called by muse, varscan2
- ELF2 | c.271T>C p.C91R (on ENST00000379550 / NM_001331036.2; = p.C31R on NM_006874.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.161); catalogued as COSV55493121; called by muse, mutect2, varscan2
- ELF3 | c.164-1G>A p.X55_splice | Splice Site (SNP) | VAF 31/95 reads (33%) | catalogued as COSV62838303; called by muse, mutect2, varscan2
- ELN | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1554683519, COSV52710174; called by muse, mutect2, varscan2
- EML3 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV53871984; called by muse, mutect2, varscan2
- ENGASE | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs376807981, COSV56135439; called by muse, mutect2, varscan2
- ENPP4 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV58088976; called by muse, mutect2, varscan2
- ENTPD3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs771858873, COSV57194362; called by muse, mutect2, varscan2
- EP300 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV54329131; called by muse, mutect2, varscan2
- EPG5 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56349572; called by muse, mutect2, varscan2
- EPHA2 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100626124; called by muse, mutect2, varscan2
- EPS8L2 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs746324962, COSV59347913; called by muse, mutect2, varscan2
- EPS8L2 | c.1799A>T p.K600I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV100585551; called by muse, mutect2
- ERBB3 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV57253171, COSV57263580; called by muse, mutect2, varscan2
- ERN2 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1442722511, COSV55622114; called by muse, mutect2, varscan2
- ESF1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV52520878; called by muse, mutect2
- ESYT1 | c.1447T>C p.Y483H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1177062772, COSV57272975; called by muse, mutect2, varscan2
- ESYT3 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67440851; called by muse, mutect2, varscan2
- ETAA1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1368543937, COSV55472997; called by muse, mutect2, varscan2
- ETNK2 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV65819806; called by muse, mutect2, varscan2
- EXOC8 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99149767; called by muse, mutect2, varscan2
- EXOSC7 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV55556546; called by muse, mutect2, varscan2
- F12 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1277944447, COSV99499707; called by muse, mutect2
- F5 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs764814710, COSV63123808; called by muse, mutect2
- FAM114A1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.233); catalogued as COSV62672884; called by muse, mutect2, varscan2
- FAM117B | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs1362085010, COSV100287495; called by muse, mutect2, varscan2
- FAM120C | c.2313-2A>G p.X771_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV60257577, COSV60259340; called by muse, mutect2, varscan2
- FAM122A | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55247728; called by muse, mutect2, varscan2
- FAM193A | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV61193999; called by muse, mutect2, varscan2
- FAM204A | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV64987692; called by muse, mutect2, varscan2
- FAM43A | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.766); catalogued as rs1425838088, COSV100316468; called by muse, varscan2
- FAM83B | c.1915T>C p.Y639H | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs751730940, COSV60922042; called by muse, mutect2, varscan2
- FAM83C | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199571076; called by muse, mutect2, varscan2
- FAM98A | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99479291; called by muse, mutect2, varscan2
- FANCB | c.1801A>G p.I601V | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV60759871; called by muse, mutect2, varscan2
- FAT1 | c.8503G>A p.D2835N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71673852, COSV71676589; called by muse, mutect2, varscan2
- FAT1 | c.6880G>A p.E2294K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1447875048, COSV101499647, COSV71673856; called by muse, mutect2, varscan2
- FAT1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71673858; called by muse, mutect2, varscan2
- FAT3 | c.7012C>T p.H2338Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV53109214; called by muse, mutect2, varscan2
- FBN1 | c.4951G>A p.E1651K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs886039152, COSV57316378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL7 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61645795; called by muse, mutect2, varscan2
- FBXO22 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs750180280, COSV51193115; called by muse, mutect2, varscan2
- FBXO34 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58254525; called by muse, mutect2, varscan2
- FBXO34 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs535237309, COSV58254210, COSV58255842; called by muse, mutect2, varscan2
- FBXO38 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV57027724; called by muse, mutect2, varscan2
- FBXW7 | c.1193C>T p.S398F (on ENST00000281708 / NM_001349798.2; = p.S318F on NM_018315.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55915633, COSV55933240; called by muse, mutect2, varscan2
- FES | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs770735267, COSV51576690; called by mutect2, varscan2
- FGA | c.1388A>T p.K463I | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57395956; called by muse, mutect2, varscan2
- FGD4 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as COSV99847076; called by muse, mutect2, varscan2
- FHL3 | c.156+2T>C p.X52_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV65952489; called by muse, mutect2, varscan2
- FHOD1 | c.3260C>T p.S1087F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50760844; called by muse, mutect2, varscan2
- FILIP1L | c.1609G>A p.E537K (on ENST00000354552 / NM_182909.3; = p.E297K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58768853; called by muse, mutect2, varscan2
- FJX1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100502797, COSV58553013; called by muse, mutect2
- FKBP8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55892311; called by muse, mutect2, varscan2
- FLT1 | c.3485T>A p.V1162E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56727633; called by muse, mutect2, varscan2
- FN1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60549418; called by muse, mutect2, varscan2
- FOXE1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1227098969, COSV64300423, COSV64300473; called by muse, mutect2, varscan2
- FREM1 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101085723, COSV66517749, COSV66518799; called by muse, mutect2, varscan2
- FRMD7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV53746121; called by muse, mutect2, varscan2
- FRY | c.2472G>A p.W824* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100969303; called by muse, mutect2, varscan2
- FRYL | c.5477C>T p.A1826V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1278885395, COSV51946810; called by muse, mutect2, varscan2
- FSHR | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.522); catalogued as COSV58623451; called by muse, mutect2, varscan2
- FUCA1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs779512930, COSV65699126; called by muse, mutect2, varscan2
- GABPB1 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs375555413; called by muse, mutect2, varscan2
- GAK | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV58504640; called by muse, mutect2, varscan2
- GALNT13 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV67221080; called by muse, mutect2, varscan2
- GALNT2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139591495; called by muse, mutect2, varscan2
- GALNT5 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs143195308; called by muse, mutect2, varscan2
- GARNL3 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV59226257; called by muse, mutect2, varscan2
- GARNL3 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59226269; called by muse, mutect2, varscan2
- GDF5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/34 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs1279365396, COSV65501482, COSV65501551; called by muse, mutect2, varscan2
- GDF6 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54624943; called by muse, mutect2, varscan2
- GDF9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as COSV51526334; called by muse, mutect2, varscan2
- GEMIN6 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56140349; called by muse, mutect2, varscan2
- GLIS2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52110577; called by muse, mutect2, varscan2
- GMFB | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV63737766; called by muse, mutect2, varscan2
- GMPS | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748546400, COSV55809415; called by muse, mutect2, varscan2
- GNS | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs751200375, COSV50694707; called by muse, mutect2, varscan2
- GOLGA3 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV52627440; called by muse, mutect2, varscan2
- GOLGA4 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV62710658; called by muse, mutect2, varscan2
- GOLGB1 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV61465730; called by muse, varscan2
- GOLM1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs769644477, COSV99974361; called by muse, mutect2, varscan2
- GPATCH4 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV58039726; called by muse, mutect2, varscan2
- GPR148 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs780327331, COSV59308243, COSV99998725; called by muse, mutect2, varscan2
- GPR149 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV101078451; called by muse, mutect2, varscan2
- GPR18 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV61621208; called by muse, mutect2, varscan2
- GPR180 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1230215712, COSV65385580; called by muse, mutect2, varscan2
- GPR4 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200574979, COSV59916987; called by muse, mutect2, varscan2
- GPR82 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 40/76 reads (53%) | catalogued as rs1254822592, COSV100220601; called by muse, mutect2, varscan2
- GPRASP1 | c.2408T>C p.L803P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.894); catalogued as COSV64355568; called by muse, mutect2, varscan2
- GPRC5D | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV57433219, COSV99964234; called by muse, mutect2, varscan2
- GRAMD4 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1369124000, COSV63030287; called by muse, mutect2, varscan2
- GRIA1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53602630; called by muse, mutect2, varscan2
- GRIA2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.864); catalogued as COSV52390242; called by muse, mutect2, varscan2
- GRIK2 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777004979, COSV59735726; called by muse, mutect2, varscan2
- GRIN2A | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58032369, COSV58057145; called by muse, mutect2, varscan2
- GSDME | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs762267830, COSV61651645; called by muse, mutect2, varscan2
- GSR | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV55320630; called by muse, mutect2, varscan2
- GTF3C1 | c.4679C>T p.S1560L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV62241199; called by muse, mutect2, varscan2
- GTPBP3 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV50177066; called by muse, mutect2, varscan2
- GUCD1 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1417202538, COSV68035116, COSV68035706; called by muse, mutect2, varscan2
- GUCY2D | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54696196; called by muse, mutect2, varscan2
- GUCY2F | c.2924T>C p.V975A | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV54301792; called by muse, mutect2
- H1-3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as rs1266069764, COSV55096890; called by muse, mutect2, varscan2
- H1-5 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as COSV58899999; called by muse, mutect2, varscan2
- H2AX | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53828488, COSV99597813; called by muse, mutect2, varscan2
- H2BC21 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV58611970; called by muse, mutect2, varscan2
- HACD4 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1455068998, COSV101529970, COSV72136707; called by muse, mutect2
- HAS2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58262207, COSV58263921; called by muse, mutect2, varscan2
- HAUS5 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99178561; called by muse, mutect2, varscan2
- HAUS6 | c.645A>G p.I215M | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV63252921; called by muse, mutect2, varscan2
- HBEGF | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50182526; called by muse, mutect2, varscan2
- HCFC2 | c.1399T>A p.S467T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV57558264; called by muse, mutect2, varscan2
- HEATR5A | c.5467G>A p.D1823N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV101120011; called by muse, mutect2
- HEATR5B | c.5537C>T p.S1846F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV51852573; called by muse, mutect2, varscan2
- HECTD1 | c.76A>C p.I26L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV67946291; called by muse, mutect2, varscan2
- HECTD4 | c.11014C>G p.L3672V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66391913; called by muse, mutect2, varscan2
- HERC1 | c.8572C>T p.H2858Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV101496579; called by muse, mutect2
- HEXIM1 | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV60177067; called by muse, mutect2, varscan2
- HIKESHI | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs868726094, COSV53573957; called by muse, mutect2, varscan2
- HIRIP3 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV54229891; called by muse, mutect2, varscan2
- HIVEP2 | c.5900C>T p.S1967L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs756560364, COSV50008259; called by muse, mutect2, varscan2
- HIVEP2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV50012607; called by muse, mutect2, varscan2
- HLA-G | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.568); catalogued as rs1459341178, COSV64405677; called by muse, mutect2, varscan2
- HMCN1 | c.6555A>T p.K2185N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54899895; called by muse, mutect2, varscan2
- HMGCS2 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1002548815, CM154432, COSV65567871; called by muse, mutect2, varscan2
- HMGN1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1234463105, COSV55742480; called by muse, mutect2, varscan2
- HOMER2 | c.1015G>A p.D339N (on ENST00000304231 / NM_199330.3; = p.D328N on NM_004839.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1280116567, COSV58486058; called by muse, mutect2
- HOXA10 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52228865; called by muse, mutect2, varscan2
- HOXA5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.369); catalogued as rs764896847, COSV56072957; called by muse, mutect2, varscan2
- HOXA7 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs770523270, COSV54217182; called by muse, mutect2, varscan2
- HOXA7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV99636306; called by muse, varscan2
- HOXB1 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53317230; called by muse, mutect2, varscan2
- HOXB1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99495511; called by muse, mutect2, varscan2
- HS3ST6 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53534530; called by muse, mutect2, varscan2
- HSD17B14 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs775465888, COSV54413438; called by muse, varscan2
- HSD17B4 | c.1309G>A p.E437K (on ENST00000414835 / NM_001199291.3; = p.E412K on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV56335661; called by muse, mutect2, varscan2
- HSPA1B | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65148329; called by muse, mutect2, varscan2
- HSPA4 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100507668; called by muse, mutect2
- HSPA9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.022); catalogued as rs1159773684, COSV51864414; called by muse, mutect2, varscan2
- HSPB9 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56790773, COSV56792984; called by muse, mutect2, varscan2
- HYDIN | c.12594G>T p.R4198S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101125089; called by muse, mutect2, varscan2
- IBTK | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60392826; called by muse, mutect2, varscan2
- ICAM5 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs1414106315, COSV55747257; called by muse, mutect2, varscan2
- ICE1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1483187648, COSV99664804; called by muse, mutect2, varscan2
- ICE2 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV55031380; called by muse, mutect2, varscan2
- IDH3A | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 23/63 reads (37%) | catalogued as COSV51905916; called by muse, mutect2, varscan2
- IFNA2 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV66505579; called by muse, mutect2, varscan2
- IFNE | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV58640992; called by muse, mutect2, varscan2
- IHO1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56507681; called by muse, mutect2, varscan2
- IL9R | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99729804; called by muse, mutect2, varscan2
- IMPDH1 | c.1449C>A p.Y483* (on ENST00000470772 / NM_001142573.2; = p.Y569* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100118687; called by muse, mutect2, varscan2
- INKA1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV58526143; called by muse, mutect2, varscan2
- INPP5D | c.319del p.D107Tfs*11 (on ENST00000445964 / NM_001017915.3; = p.D107Tfs*26 on NM_005541.5) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV64037096; called by mutect2, pindel, varscan2
- INTS1 | c.4948C>T p.Q1650* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs1350068308, COSV101247933; called by muse, mutect2, varscan2
- IPO7 | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101121781, COSV65685068; called by muse, mutect2, varscan2
- IPO8 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV56241609; called by muse, mutect2, varscan2
- IPO9 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs1296706416, COSV64233679; called by muse, mutect2, varscan2
- IQUB | c.532+2T>A p.X178_splice | Splice Site (SNP) | VAF 64/197 reads (32%) | catalogued as COSV61239202; called by muse, mutect2, varscan2
- IRF2BPL | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53147147; called by muse, mutect2, varscan2
- IRF9 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV60703200; called by muse, mutect2, varscan2
- ITGAV | c.2817G>A p.M939I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs761261370, COSV53712254; called by muse, mutect2, varscan2
- ITGB1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV56481584; called by muse, mutect2, varscan2
- ITGB4 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52325803; called by muse, mutect2, varscan2
- ITGB8 | c.2142T>A p.N714K | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV56008478; called by muse, mutect2, varscan2
- ITIH1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs760443050, COSV56254892; called by muse, mutect2, varscan2
- ITPKC | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54574682; called by muse, mutect2, varscan2
- ITPR2 | c.6098G>A p.R2033Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs757432129, COSV67265715; called by muse, mutect2, varscan2
- ITPR3 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV65409074; called by muse, mutect2, varscan2
- JAG1 | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894508274, COSV54756656; called by muse, mutect2, varscan2
- JAK1 | c.2891T>G p.L964R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090879; called by muse, mutect2, varscan2
- JAK1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100691732, COSV61090216; called by muse, mutect2, varscan2
- JAKMIP2 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs368841711; called by muse, mutect2
- JMJD4 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs148842395; called by muse, mutect2, varscan2
- JUNB | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1402249326, COSV56877474; called by muse, mutect2, varscan2
- KALRN | c.7825G>A p.E2609K (on ENST00000360013 / NM_001024660.4; = p.E912K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV99362084; called by muse, mutect2
- KANSL1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs1173584837, COSV52268182; called by muse, mutect2
- KBTBD2 | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58363440; called by muse, mutect2, varscan2
- KCND2 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs1200276294, COSV58579800; called by muse, varscan2
- KCNJ15 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs549879402, COSV60810848; called by muse, mutect2, varscan2
- KCNK13 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as rs1266403083, COSV56413058; called by muse, mutect2, varscan2
- KCNK5 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV63988888; called by muse, mutect2, varscan2
- KCNQ5 | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59659510, COSV99050819; called by muse, mutect2, varscan2
- KCNQ5 | c.1657T>C p.Y553H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59659538; called by muse, mutect2, varscan2
- KCNQ5 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1255166079, COSV59659559; called by muse, mutect2, varscan2
- KCTD19 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); catalogued as COSV58572861; called by muse, mutect2, varscan2
- KDM5A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66992327; called by muse, mutect2, varscan2
- KDM6B | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1429197829, COSV54681475, COSV99640984; called by muse, mutect2, varscan2
- KIAA1522 | c.2338C>T p.P780S (on ENST00000373480 / NM_001198972.2; = p.P839S on NM_020888.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV53862436; called by muse, mutect2, varscan2
- KIAA1614 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs929507879, COSV62550861; called by muse, mutect2, varscan2
- KIAA1614 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV62550865; called by muse, mutect2, varscan2
- KIF18B | c.2301G>A p.M767I (on ENST00000593135 / NM_001265577.2; = p.M779I on NM_001264573.2) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV59272967; called by muse, mutect2, varscan2
- KIF18B | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV100192201; called by muse, mutect2
- KIF20A | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.76); catalogued as rs1198604545, COSV67509812; called by muse, mutect2, varscan2
- KIF23 | c.2389C>T p.Q797* (on ENST00000260363; = p.Q693* on NM_004856.7) | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs1409403326, COSV99532353; called by muse, mutect2, varscan2
- KIFC2 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1359699630, COSV100023806; called by muse, mutect2
- KIT | c.1116-1G>A p.X372_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV55400044, COSV55411329; called by muse, mutect2, varscan2
- KLC3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs759945535, COSV67268039; called by muse, mutect2, varscan2
- KLF10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as COSV53435525; called by muse, mutect2, varscan2
- KLF5 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66614393; called by muse, varscan2
- KLF6 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs762548312, COSV51493879, COSV51495172; called by muse, mutect2, varscan2
- KLHL2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV56976838; called by muse, mutect2, varscan2
- KLHL31 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63881738; called by muse, mutect2
- KLHL42 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV67145871; called by muse, mutect2, varscan2
- KLK6 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs138116440, COSV59565038; called by muse, mutect2, varscan2
- KMT2C | c.8683C>T p.Q2895* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV51298634; called by muse, mutect2, varscan2
- KMT2C | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV51509345, COSV51518404; called by muse, mutect2, varscan2
- KMT2D | c.10633A>T p.K3545* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99982004; called by muse, mutect2, varscan2
- KMT2D | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV56470912; called by muse, mutect2, varscan2
- KPNA1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100724373, COSV60268932; called by muse, mutect2, varscan2
- KRBA2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58779025; called by muse, varscan2
- KRBA2 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs773828886, COSV58779031; called by muse, varscan2
- KRT17 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV60860804, COSV60861067; called by muse, mutect2, varscan2
- KRT18 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs11551626, COSV66316187; called by muse, mutect2, varscan2
- KRT19 | c.952_957del p.A318_A319del | In Frame Del (DEL) | VAF 16/53 reads (30%) | catalogued as COSV54179453; called by mutect2, pindel, varscan2
- KRT37 | c.1249T>C p.C417R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV99845486; called by muse, mutect2
- KRT79 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV57940010; called by muse, mutect2, varscan2
- KRTAP1-5 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.096); catalogued as rs766745380, COSV62624252; called by muse, varscan2
- KRTAP5-9 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | catalogued as COSV101603633; called by muse, mutect2, varscan2
- LAMA4 | c.3985G>A p.D1329N (on ENST00000230538 / NM_001105206.3; = p.D1322N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57896940; called by muse, mutect2, varscan2
- LAMA4 | c.1856A>C p.K619T (on ENST00000230538 / NM_001105206.3; = p.K612T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57896968; called by muse, mutect2, varscan2
- LAMB4 | c.4048A>G p.T1350A | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV52718886; called by muse, mutect2, varscan2
- LAMC1 | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); catalogued as rs781075791, COSV51141354; called by muse, mutect2, varscan2
- LAMP3 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV55614843; called by muse, mutect2, varscan2
- LAPTM4B | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1361775107, COSV63392858; called by muse, mutect2, varscan2
- LARP1 | c.2800G>T p.E934* (on ENST00000518297 / NM_033551.3; = p.E857* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100303772; called by muse, mutect2, varscan2
- LARS2 | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV55527524; called by muse, mutect2, varscan2
- LCE5A | c.318_344del p.G107_G115del | In Frame Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs751294583; called by muse*, mutect2
- LDLRAP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as COSV65473550; called by muse, mutect2, varscan2
- LIFR | c.2157A>G p.I719M | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs367749984; called by muse, mutect2, varscan2
- LILRB1 | c.595G>A p.E199K (on ENST00000427581; = p.E163K on NM_006669.6) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV61117897; called by muse, mutect2, varscan2
- LIMA1 | c.1052A>G p.E351G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV57965432; called by muse, mutect2, varscan2
- LIMA1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs749831700, COSV57965442; called by muse, mutect2, varscan2
- LMNB2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.457); catalogued as COSV57587970; called by muse, mutect2, varscan2
- LMTK2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV51995528; called by muse, mutect2, varscan2
- LONP2 | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV53522399; called by muse, mutect2, varscan2
- LOXL3 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99284067; called by muse, mutect2
- LPA | c.3448A>T p.T1150S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.511); catalogued as COSV60301764; called by muse, mutect2, varscan2
- LPGAT1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.922); catalogued as COSV65351578; called by muse, mutect2, varscan2
- LRFN1 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as rs1449915461, COSV99952964; called by muse, mutect2, varscan2
- LRFN5 | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.345); catalogued as COSV53255916; called by muse, mutect2, varscan2
- LRGUK | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV53637751; called by muse, mutect2, varscan2
- LRIG2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1185471048, COSV63162076; called by muse, mutect2, varscan2
- LRP1 | c.13259-1G>T p.X4420_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54510957; called by muse, varscan2
- LRP1 | c.13268C>T p.S4423F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV54510967; called by muse, varscan2
- LRP10 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs1234871117, COSV62078221; called by muse, mutect2, varscan2
- LRP6 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV53787212; called by muse, mutect2, varscan2
- LRRC37A2 | c.3812G>A p.R1271K | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100238752; called by muse, mutect2, varscan2
- LTB4R | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51865185, COSV51865745; called by muse, mutect2, varscan2
- LTB4R2 | c.484C>T p.R162W (on ENST00000528054; = p.R131W on NM_019839.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1566422837, COSV99350733; called by muse, mutect2, varscan2
- LTN1 | c.5020C>T p.Q1674* | Nonsense Mutation (SNP) | VAF 62/176 reads (35%) | catalogued as COSV100798006; called by muse, mutect2, varscan2
- LTN1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); catalogued as COSV63733774; called by muse, mutect2, varscan2
- LYSMD2 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51056841, COSV51057014; called by muse, mutect2, varscan2
- M1AP | c.596-1G>A p.X199_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV51844571; called by muse, mutect2, varscan2
- MACF1 | c.3074G>T p.C1025F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV58373046; called by muse, varscan2
- MACF1 | c.21847G>A p.D7283N (on ENST00000372915; = p.D5328N on NM_012090.5) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as rs1163784106, COSV57116983, COSV57146428; called by muse, mutect2, varscan2
- MACO1 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394898926, COSV65476486; called by muse, mutect2, varscan2
- MACO1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65476491; called by muse, mutect2, varscan2
- MAGED2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.197); catalogued as COSV54497867; called by mutect2, varscan2
- MAN1A2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs755034906, COSV62978423; called by muse, mutect2, varscan2
- MAN1A2 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62978429; called by muse, mutect2, varscan2
- MAN1B1 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65371323; called by muse, mutect2, varscan2
- MAN2B1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as rs978130289, COSV55471928; called by muse, mutect2, varscan2
- MAP10 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69363595; called by muse, mutect2, varscan2
- MAP3K5 | c.3433C>T p.H1145Y | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV62889133; called by muse, mutect2, varscan2
- MAP4K3 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55713029; called by muse, mutect2, varscan2
- MAP7D1 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60216334; called by mutect2, varscan2
- MAPK15 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | catalogued as COSV100567890; called by muse, mutect2, varscan2
- MAPKAP1 | c.1429G>A p.E477K (on ENST00000265960 / NM_001006617.3; = p.E441K on NM_024117.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV56367698; called by muse, mutect2, varscan2
- MARCKS | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV64042561, COSV64042798; called by muse, mutect2, varscan2
- MARS1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs989362165, COSV56254696; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs746267361; called by mutect2, varscan2
- MBTPS1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58570475, COSV58571565; called by muse, mutect2, varscan2
- MCM9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV60164220; called by muse, mutect2, varscan2
- MDC1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV64524571, COSV64525773; called by muse, mutect2, varscan2
- MECOM | c.3013A>T p.K1005* (on ENST00000468789 / NM_001105078.4; = p.K1193* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV99244746; called by muse, mutect2, varscan2
- MECOM | c.613C>T p.R205C (on ENST00000468789 / NM_001105078.4; = p.R393C on NM_004991.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201758074, COSV52963046, COSV52964249, COSV52973072; called by muse, mutect2, varscan2
- MED12 | c.5671T>G p.S1891A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.299); catalogued as COSV61339688; called by muse, mutect2, varscan2
- MED12L | c.5564C>T p.S1855L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56378683; called by muse, mutect2, varscan2
- MED13 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100784901; called by muse, mutect2, varscan2
- MED16 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV54126274; called by muse, mutect2, varscan2
- MED29 | c.101C>T p.S34L (on ENST00000615911; = p.S13L on NM_017592.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV55394079; called by muse, mutect2, varscan2
- MEF2C | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV60930810; called by muse, mutect2, varscan2
- MEGF6 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as rs377315812; called by muse, mutect2
- MERTK | c.1694A>T p.H565L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV54928852; called by muse, mutect2, varscan2
- METTL23 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as CD147298, COSV57972331; called by muse, mutect2, varscan2
- MFHAS1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs866777616, COSV99359597; called by muse, mutect2, varscan2
- MFSD4A | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs868615001, COSV65656446; called by muse, mutect2, varscan2
- MGAT1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen possibly damaging (0.601); catalogued as rs756554434, COSV57134040; called by muse, mutect2, varscan2
- MIB1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV99838811; called by muse, mutect2, varscan2
- MIB2 | c.2909-1G>C p.X970_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as COSV61542509; called by muse, mutect2
- MIDEAS | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV54094845; called by muse, mutect2, varscan2
- MINDY1 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV56498749; called by muse, mutect2, varscan2
- MINDY1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1481796100, COSV56498766; called by muse, mutect2, varscan2
- MINDY4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV54672524, COSV54673785; called by muse, mutect2, varscan2
- MINPP1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV64354365, COSV64355804; called by muse, mutect2, varscan2
- MIOX | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV53312654; called by muse, mutect2, varscan2
- MIPOL1 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100538855; called by muse, varscan2
- MITF | c.595G>A p.E199K (on ENST00000448226 / NM_006722.3; = p.E93K on NM_000248.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.647); catalogued as rs965705838, COSV58831410; called by muse, mutect2, varscan2
- MLST8 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57028073; called by muse, mutect2, varscan2
- MMP1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV59510391; called by muse, mutect2, varscan2
- MMP27 | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52780813, COSV52781560; called by muse, mutect2, varscan2
- MMS22L | c.1197A>C p.E399D | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51520760; called by muse, mutect2, varscan2
- MMS22L | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV51520774; called by muse, mutect2, varscan2
- MON1B | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.025); catalogued as COSV50246970; called by muse, mutect2, varscan2
- MOV10 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs1476171944, COSV53516913; called by muse, mutect2, varscan2
- MPP5 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs369975260; called by muse, mutect2, varscan2
- MRPL40 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54274843; called by muse, mutect2, varscan2
- MRPL44 | c.420_435del p.L141Qfs*8 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as COSV51312649; called by mutect2, pindel, varscan2
- MRPL58 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV56900596; called by muse, varscan2
- MRPL58 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs770515306, COSV56900823; called by muse, varscan2
- MS4A14 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV55734850; called by muse, mutect2, varscan2
- MSANTD3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs762011399, COSV58493579; called by muse, mutect2, varscan2
- MST1R | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.211); catalogued as COSV56568710; called by muse, mutect2, varscan2
- MTF1 | c.688A>T p.N230Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65989045; called by muse, mutect2, varscan2
- MTHFD1L | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs775876412, COSV66209661; called by muse, mutect2, varscan2
- MTREX | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV57925875; called by muse, mutect2, varscan2
- MUC16 | c.10678G>A p.G3560S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.028); catalogued as COSV67465361; called by muse, mutect2, varscan2
- MYBPC3 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748443032, COSV57027141; called by muse, mutect2, varscan2
- MYCL | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65693311; called by muse, mutect2, varscan2
- MYH11 | c.5265G>A p.M1755I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55552884, COSV55553173; called by muse, mutect2, varscan2
- MYH15 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1380182896, COSV56309797; called by muse, mutect2, varscan2
- MYL5 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs763972713, COSV100448451; called by muse, varscan2
- MYNN | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.919); catalogued as COSV57754371; called by muse, mutect2, varscan2
- MYO10 | c.4928G>C p.R1643P | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57021525, COSV57022846; called by muse, mutect2, varscan2
- MYO15A | c.9401G>A p.R3134Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373695303; called by muse, mutect2, varscan2
- MYO1E | c.3057G>T p.K1019N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55687034; called by muse, mutect2, varscan2
- MYO5B | c.4273A>C p.K1425Q | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53218382; called by muse, mutect2, varscan2
- MYO9A | c.5246C>T p.S1749L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1487134412, COSV61851000; called by muse, mutect2, varscan2
- MYO9A | c.3058C>T p.L1020F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61851008; called by muse, mutect2, varscan2
- MYOF | c.5312_5319del p.L1771Sfs*41 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as COSV63704098; called by mutect2, pindel, varscan2
- MYOM3 | c.1905C>G p.I635M | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs756110070, COSV58393654; called by muse, mutect2, varscan2
- NAA16 | c.1936A>C p.K646Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV65128350; called by muse, mutect2, varscan2
- NAA30 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1224102042, COSV53648467; called by muse, mutect2, varscan2
- NAPRT | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.141); catalogued as COSV52784992; called by muse, mutect2, varscan2
- NASP | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100601803; called by muse, mutect2
- NAV1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV55217521; called by muse, mutect2, varscan2
- NBAS | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs115462597, COSV55721572; called by muse, mutect2, varscan2
- NCAM1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57516265, COSV57525482; called by muse, mutect2
- NCAPG2 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51987526; called by muse, mutect2, varscan2
- NCAPG2 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV51987545; called by muse, mutect2, varscan2
- NCL | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59545870; called by muse, mutect2, varscan2
- NCOA1 | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV56040623; called by muse, mutect2, varscan2
- NCOR1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.222); catalogued as COSV51974382, COSV52001363; called by muse, mutect2, varscan2
- NDP | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.278); catalogued as COSV100955825, COSV65203582; called by muse, mutect2, varscan2
- NEDD9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65158864; called by muse, mutect2, varscan2
- NELFB | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100546903; called by muse, mutect2, varscan2
- NELL1 | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100122487, COSV54263969, COSV54298710; called by muse, mutect2, varscan2
- NEURL4 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.236); catalogued as rs569858150, COSV59758832; called by muse, mutect2, varscan2
- NFATC3 | c.2467T>C p.S823P | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV60473589; called by muse, mutect2, varscan2
- NFE2L2 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | catalogued as COSV101229378; called by muse, mutect2, varscan2
- NFE2L2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV67961097; called by muse, varscan2
- NHLRC2 | c.566T>A p.L189* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100992950; called by muse, mutect2, varscan2
- NKTR | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1380827039, COSV51771690; called by muse, mutect2, varscan2
- NLRP13 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs772345745, COSV61621652; called by muse, mutect2, varscan2
- NOA1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV51736958; called by muse, mutect2, varscan2
- NOL8 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV62635333, COSV62637227; called by muse, mutect2, varscan2
- NOP16 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51257622; called by muse, mutect2, varscan2
- NOP16 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs752090377, COSV51257626; called by muse, mutect2, varscan2
- NOS1AP | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62634858; called by muse, varscan2
- NOTCH3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV54634657; called by muse, mutect2, varscan2
- NPHP3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as rs1465502034, COSV100446713; called by muse, mutect2
- NPHS2 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100858172, COSV62635053; called by muse, mutect2, varscan2
- NR2F2 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67683483; called by muse, mutect2, varscan2
- NRIP1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV59657276; called by muse, mutect2, varscan2
- NRP2 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV55928178; called by muse, mutect2, varscan2
- NRXN1 | c.1487G>T p.W496L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV100453614, COSV58452059, COSV58453816; called by muse, mutect2, varscan2
- NSA2 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV57188024; called by muse, mutect2, varscan2
- NUFIP1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.537); catalogued as rs781382296, COSV100742129, COSV63152389; called by muse, mutect2, varscan2
- NUP35 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54557877, COSV54559438; called by muse, mutect2, varscan2
- NUP88 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56705204; called by muse, mutect2, varscan2
- NXT2 | c.55G>A p.E19K (on ENST00000372106 / NM_001242617.2; = p.E74K on NM_018698.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54296505, COSV54296730; called by muse, mutect2, varscan2
- NYNRIN | c.5032G>A p.E1678K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66842394; called by muse, mutect2, varscan2
- OLIG1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs772224219, COSV60737962; called by muse, mutect2, varscan2
- OLR1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV58871522; called by muse, mutect2, varscan2
- OR10S1 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV73342790; called by muse, mutect2, varscan2
- OR4N2 | c.550G>C p.V184L | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.232); catalogued as COSV60051449; called by muse, varscan2
- OR5R1 | c.954A>T p.L318F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as rs141438285; called by muse, mutect2, varscan2
- OR6B1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68770131; called by muse, mutect2, varscan2
- OR7C2 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV50180621; called by muse, mutect2, varscan2
- OR8J3 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV56880716; called by muse, mutect2, varscan2
- ORC1 | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100856670; called by muse, mutect2, varscan2
- ORMDL1 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57877029; called by muse, mutect2, varscan2
- OSTF1 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60547408; called by muse, mutect2, varscan2
- OTOF | c.4708G>A p.D1570N (on ENST00000272371 / NM_194248.3; = p.D803N on NM_004802.4) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55502802; called by muse, mutect2, varscan2
- OTOGL | c.5518G>A p.E1840K (on ENST00000547103; = p.E1831K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1259827721, COSV100087290; called by muse, mutect2, varscan2
- OTUD7B | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV64916098; called by muse, mutect2, varscan2
- OTX1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs776338153, COSV56994461, COSV99246546; called by muse, mutect2
- PA2G4 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57568507; called by muse, mutect2, varscan2
- PABPC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100865464; called by muse, mutect2
- PACS2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57652625; called by muse, mutect2, varscan2
- PACSIN3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as COSV54066063; called by muse, mutect2, varscan2
- PAK1IP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV52584469, COSV99468416, COSV99468494; called by muse, mutect2, varscan2
- PALMD | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54164449; called by muse, mutect2, varscan2
- PAN2 | c.2647G>A p.E883K (on ENST00000425394 / NM_001127460.3; = p.E879K on NM_014871.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV57753800; called by muse, mutect2, varscan2
- PAXBP1 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51609002; called by muse, mutect2, varscan2
- PC | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469115511, COSV63080525; called by muse, mutect2, varscan2
- PCBD2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as rs770064476, COSV54737131; called by muse, mutect2, varscan2
- PCDH11X | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53445165; called by muse, mutect2, varscan2
1,187 further variants in this file (533 protein-altering or splice-affecting, 602 silent, 52 other) are not listed here.
